CCDI case PBCKSN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/4d0b7acc-3fd2-4a1c-8535-126ee3283892

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Gastrointestinal stromal tumor, benign: ICD-O-3 morphology code: 8936/0; Tissue or organ of origin: Body of stomach; Age at diagnosis: 11.9 years (4,347 days).

Biospecimens (3 samples)
- Sample 0DUNO7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUNOY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUNPC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
